Somatic mutation profile of tumor specimen 0DMEUA from CCDI case PBBZYM, project CCDI-MCI: Molecular Characterization Initiative (MCI). Sex at birth: male; Primary diagnosis: Malignant lymphoma, non-Hodgkin, NOS; Tissue or organ of origin: Lymph nodes of head, face and neck; Age at diagnosis: 14.4 years (5,259 days).
Specimen 0DMEUA: Tissue type: Tumor; Specimen type: Solid Tissue; Preservation method: FFPE.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) d1a144d9-e113-4ff0-b6c1-b8b40dcbe624.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen 0DMEUJ (Peripheral Whole Blood; tissue type Normal); read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/eced92a8-b5ed-482b-ac16-4e288187d54b

The open-access MAF lists 25 somatic variants for this specimen: 16 protein-altering or splice-affecting, 3 silent, 6 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 16, Intron 3, Silent 3, 5'UTR 2, RNA 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- CDH12 | c.2352A>C p.E784D | Missense Mutation (SNP) | VAF 47/974 reads (5%) | SIFT tolerated (0.58); PolyPhen benign (0.245); catalogued as COSV66394408; called by muse, mutect2
- DNAH14 | c.2485G>A p.D829N (on ENST00000445597; = p.D895N on NM_001367479.1) | Missense Mutation (SNP) | VAF 26/652 reads (4%) | SIFT deleterious (0); PolyPhen benign (0.017); catalogued as COSV60737149; called by muse, mutect2
- MET | c.2684C>T p.T895M | Missense Mutation (SNP) | VAF 42/884 reads (5%) | SIFT deleterious (0.05); PolyPhen possibly damaging (0.749); catalogued as rs199502137; ClinVar: uncertain significance; called by muse, mutect2
- PAPPA2 | c.4636C>T p.H1546Y | Missense Mutation (SNP) | VAF 51/816 reads (6%) | SIFT deleterious (0); PolyPhen benign (0.348); catalogued as COSV62799156; called by muse, mutect2
- THSD4 | c.695G>A p.R232H | Missense Mutation (SNP) | VAF 38/596 reads (6%) | SIFT tolerated (0.61); PolyPhen benign (0); catalogued as rs375872892; called by muse, mutect2
- ZFC3H1 | c.2000G>A p.R667K | Missense Mutation (SNP) | VAF 38/816 reads (5%) | SIFT tolerated (0.07); PolyPhen possibly damaging (0.584); catalogued as COSV101110593; called by muse, mutect2
- ZNF652 | c.772T>G p.W258G | Missense Mutation (SNP) | VAF 43/612 reads (7%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.966); catalogued as COSV100755733; called by muse, mutect2
- ALDH1A3 | c.1187C>T p.T396I | Missense Mutation (SNP) | VAF 37/747 reads (5%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); called by muse, mutect2
- DOCK4 | c.4216A>G p.S1406G | Missense Mutation (SNP) | VAF 32/864 reads (4%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.932); called by muse, mutect2
- EN1 | c.1042A>G p.K348E | Missense Mutation (SNP) | VAF 20/364 reads (5%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); called by muse, mutect2
- GUCY2D | c.2262G>T p.E754D | Missense Mutation (SNP) | VAF 36/701 reads (5%) | SIFT deleterious (0.04); PolyPhen benign (0.021); called by muse, mutect2
- LAMB4 | c.3176T>A p.L1059Q | Missense Mutation (SNP) | VAF 14/443 reads (3%) | SIFT tolerated (0.7); PolyPhen benign (0.012); called by muse, mutect2
- SPTA1 | c.2064G>C p.Q688H | Missense Mutation (SNP) | VAF 24/592 reads (4%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.897); called by muse, mutect2
- STAT5A | c.1667C>T p.S556F | Missense Mutation (SNP) | VAF 34/672 reads (5%) | SIFT deleterious (0); PolyPhen benign (0.28); called by muse, mutect2
- UNC80 | c.2674A>G p.T892A | Missense Mutation (SNP) | VAF 36/917 reads (4%) | SIFT tolerated (0.86); PolyPhen benign (0.037); called by muse, mutect2
- ZFHX3 | c.933A>C p.E311D | Missense Mutation (SNP) | VAF 30/768 reads (4%) | SIFT tolerated (0.34); PolyPhen benign (0.137); called by muse, mutect2
- ASPG | c.376C>T p.L126= | Silent (SNP) | VAF 54/811 reads (7%) | catalogued as rs1382708353; called by muse, mutect2
- CDK5RAP2 | c.3681C>T p.I1227= | Silent (SNP) | VAF 33/891 reads (4%) | catalogued as COSV62572703; called by muse, mutect2
- WNK1 | c.1077C>T p.G359= | Silent (SNP) | VAF 49/1196 reads (4%) | called by muse, mutect2
- MUC19 | n.23145C>T | RNA (SNP) | VAF 21/674 reads (3%) | called by muse, mutect2
- NRCAM | c.-57C>A | 5'UTR (SNP) | VAF 20/409 reads (5%) | catalogued as rs926414386, COSV100695372; called by muse, mutect2
- NRCAM | c.-58T>G | 5'UTR (SNP) | VAF 19/392 reads (5%) | called by muse, mutect2
- PES1 | c.1169+21G>A | Intron (SNP) | VAF 39/325 reads (12%) | catalogued as rs369765120; called by muse, mutect2, varscan2
- RARG | c.185-4230T>A | Intron (SNP) | VAF 19/350 reads (5%) | called by muse, mutect2
- U2SURP | c.1854-9G>A | Intron (SNP) | VAF 28/295 reads (9%) | called by muse, mutect2
